Somatic mutation profile of tumor specimen HCM-CSHL-0181-C25-01A (aliquot HCM-CSHL-0181-C25-01A-11D-A79L-36) from HCMI case HCM-CSHL-0181-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.0 years (21,919 days).
Specimen HCM-CSHL-0181-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4a7a8bc-7868-4f38-aa30-72d344eb7ac3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0181-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0181-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/680f24ab-c01d-463c-a7fa-ef01576e158f

The open-access MAF lists 116 somatic variants for this specimen: 89 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 20, Nonsense Mutation 7, Intron 4, 3'UTR 2, Splice Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PALB2 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 29/217 reads (13%) | catalogued as rs587778587, CM156713, COSV55163483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1251827333; called by muse, mutect2, varscan2
- BEAN1 | c.763C>A p.P255T (on ENST00000536005 / NM_001178020.3; = p.P146T on NM_001136106.5) | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1323468085; called by muse, mutect2
- CD1E | c.259A>C p.K87Q | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1377501869; called by muse, mutect2
- CDC25B | c.248G>A p.S83N (on ENST00000245960 / NM_021873.3; = p.S69N on NM_004358.4) | Missense Mutation (SNP) | VAF 50/519 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55657040; called by muse, mutect2
- CRACD | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99948695; called by muse, mutect2
- DAO | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.582); catalogued as rs763876748; called by muse, mutect2, varscan2
- DCTD | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1484370761; called by muse, mutect2
- DNAH5 | c.9538T>C p.S3180P | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375817990; called by muse, mutect2, varscan2
- EEPD1 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54203600; called by muse, mutect2, varscan2
- H1-4 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs771489271, COSV56801333; called by muse, mutect2
- HEPH | c.1268G>A p.R423Q (on ENST00000343002; = p.R156Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs748869673, COSV57958937; called by muse, mutect2
- HEY1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 33/510 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs1362659627; called by muse, mutect2
- HYDIN | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs1368857740; called by muse, varscan2
- IPO13 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.076); catalogued as rs1349299250; called by muse, mutect2
- MYH7 | c.5530G>T p.E1844* | Nonsense Mutation (SNP) | VAF 31/527 reads (6%) | catalogued as COSV62519291; called by muse, mutect2
- NDN | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59359727; called by muse, mutect2
- NOTCH3 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 49/468 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775584737, COSV54625419; called by muse, mutect2, varscan2
- OR10K1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760051434; called by muse, mutect2
- PIK3C2B | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 64/481 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs144230219; called by muse, mutect2, varscan2
- PRDM13 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 73/744 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs778602675; called by muse, mutect2
- RBP1 | c.393C>G p.F131L (on ENST00000619087 / NM_001365940.2; = p.F193L on NM_002899.5) | Missense Mutation (SNP) | VAF 54/548 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51678591; called by muse, mutect2
- SLC13A1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 54/419 reads (13%) | catalogued as rs752434859, COSV52015614; called by muse, mutect2, varscan2
- SPHKAP | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.24); catalogued as rs1266466012, COSV100764279, COSV60879334; called by muse, mutect2, varscan2
- TNXB | c.6344C>T p.T2115M (on ENST00000647633; = p.T1868M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1188559992, COSV64472694; called by muse, mutect2
- TPP1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 19/448 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV54998188; called by muse, mutect2
- TTN | c.13400C>T p.T4467I (on ENST00000591111; = p.T4421I on NM_003319.4) | Missense Mutation (SNP) | VAF 28/271 reads (10%) | PolyPhen possibly damaging (0.711); catalogued as rs376517129; called by muse, mutect2, varscan2
- YTHDC1 | c.1573C>T p.R525C (on ENST00000344157 / NM_001031732.4; = p.R507C on NM_133370.4) | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100704573, COSV100704906; called by muse, mutect2, varscan2
- A2ML1 | c.2763A>C p.K921N | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2
- ADGRG4 | c.2560A>G p.T854A | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2
- AHNAK2 | c.6951G>T p.K2317N | Missense Mutation (SNP) | VAF 36/548 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ARID5B | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP12A | c.1274T>A p.V425D | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2
- C7 | c.1082A>C p.K361T | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CACNA1S | c.1404C>A p.N468K | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CAVIN2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- CIDEC | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 32/505 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2
- DHX33 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 20/678 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- DIP2B | c.3950G>A p.G1317E | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DKK2 | c.228C>A p.Y76* | Nonsense Mutation (SNP) | VAF 24/263 reads (9%) | called by muse, mutect2
- DLGAP2 | c.2676G>T p.E892D | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); called by muse, mutect2
- DYNC2I2 | c.728T>G p.L243W | Missense Mutation (SNP) | VAF 23/435 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- EGFR | c.1073A>C p.H358P | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.103); called by muse, mutect2
- FOSL2 | c.102+1_102+7del p.X34_splice | Splice Site (DEL) | VAF 48/418 reads (11%) | called by mutect2, pindel, varscan2
- IKBKG | c.888G>C p.E296D | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); called by muse, mutect2
- INKA1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMA1 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- LAMP2 | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 14/387 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- LHX1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 33/733 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- LRP3 | c.1807C>G p.R603G | Missense Mutation (SNP) | VAF 47/721 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- LSS | c.1852T>C p.F618L | Missense Mutation (SNP) | VAF 43/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LY6K | c.175A>G p.R59G | Missense Mutation (SNP) | VAF 45/480 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2
- MAGEA8 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- MED23 | c.1122G>T p.W374C | Missense Mutation (SNP) | VAF 37/451 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MNAT1 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- MROH2A | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 44/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MXRA5 | c.3981G>C p.K1327N | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- MYH15 | c.4517G>A p.G1506D | Missense Mutation (SNP) | VAF 13/333 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2
- N4BP2 | c.5095G>C p.D1699H | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- NTN3 | c.1362C>G p.I454M | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); called by muse, mutect2
- NXPE4 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T11 | c.674T>C p.M225T | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- PDK3 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGAP3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2
- PLP1 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 21/521 reads (4%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PPEF2 | c.2054G>A p.S685N | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.963); called by muse, mutect2
- RDH10 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- RINT1 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- RNF39 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); called by muse, mutect2
- RSPH4A | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 32/385 reads (8%) | called by muse, mutect2
- SMCO2 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- SOX3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 60/783 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SP8 | c.884C>A p.A295D (on ENST00000361443 / NM_198956.4; = p.A313D on NM_182700.6) | Missense Mutation (SNP) | VAF 28/729 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- SPAM1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2
- SPG7 | c.325A>T p.K109* | Nonsense Mutation (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- STMN1 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); called by muse, mutect2
- SYNM | c.1928T>A p.V643D | Missense Mutation (SNP) | VAF 24/451 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TASOR2 | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 13/351 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2
- TGFBR2 | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 15/454 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM64C | c.409dup p.V137Gfs*27 | Frame Shift Ins (INS) | VAF 12/120 reads (10%) | called by mutect2, varscan2
- UPK3A | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2
- UQCRFS1 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 39/406 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- USP32 | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 38/459 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- VSIG10L2 | c.1991T>A p.L664Q | Missense Mutation (SNP) | VAF 29/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR49 | c.257T>A p.L86* (on ENST00000308378 / NM_001366158.1; = p.L427* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- XRCC5 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2
- ZBED6 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ZNF217 | c.2350T>G p.S784A | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- ZNF254 | c.706A>C p.K236Q | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ADGRG4 | c.7680G>C p.T2560= | Silent (SNP) | VAF 50/676 reads (7%) | called by muse, mutect2
- CDC25B | c.249C>T p.S83= (on ENST00000245960 / NM_021873.3; = p.S69= on NM_004358.4) | Silent (SNP) | VAF 50/521 reads (10%) | called by muse, mutect2
- CXCR1 | c.339C>G p.V113= | Silent (SNP) | VAF 32/588 reads (5%) | called by muse, mutect2
- CXorf38 | c.444C>T p.F148= | Silent (SNP) | VAF 16/420 reads (4%) | catalogued as rs1165165971, COSV59948237; called by muse, mutect2
- DLX5 | c.675G>A p.E225= | Silent (SNP) | VAF 48/586 reads (8%) | called by muse, mutect2
- DOK5 | c.576G>A p.T192= | Silent (SNP) | VAF 37/323 reads (11%) | catalogued as rs760518434; called by muse, mutect2, varscan2
- EOMES | c.966G>A p.A322= | Silent (SNP) | VAF 42/432 reads (10%) | catalogued as rs1202281120, COSV55416481; called by muse, mutect2
- FREM2 | c.8043G>A p.V2681= | Silent (SNP) | VAF 16/365 reads (4%) | called by muse, mutect2
- FREM3 | c.2880A>G p.L960= | Silent (SNP) | VAF 30/279 reads (11%) | called by muse, mutect2, varscan2
- GIMAP2 | c.657C>T p.Y219= | Silent (SNP) | VAF 38/338 reads (11%) | called by muse, varscan2
- ITCH | c.2421A>G p.K807= (on ENST00000262650 / NM_001257137.3; = p.K766= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/274 reads (5%) | called by muse, mutect2
- KRT84 | c.1464C>T p.S488= | Silent (SNP) | VAF 17/435 reads (4%) | called by muse, mutect2
- PATE2 | c.237G>A p.S79= | Silent (SNP) | VAF 33/306 reads (11%) | catalogued as rs377705832; called by muse, mutect2, varscan2
- PHF8 | c.1833C>T p.N611= (on ENST00000357988 / NM_001184896.1; = p.N575= on NM_015107.3) | Silent (SNP) | VAF 26/287 reads (9%) | catalogued as rs374668419, COSV57678138; ClinVar: likely benign; called by muse, mutect2
- RBFOX1 | c.384C>T p.F128= | Silent (SNP) | VAF 29/343 reads (8%) | catalogued as rs536057811, COSV60959510; called by muse, mutect2
- RFX1 | c.2269C>T p.L757= | Silent (SNP) | VAF 32/644 reads (5%) | called by muse, mutect2
- SLC49A4 | c.1125A>T p.L375= | Silent (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- STAG1 | c.3615C>A p.S1205= | Silent (SNP) | VAF 27/416 reads (6%) | called by muse, mutect2
- TRIM37 | c.2532T>C p.S844= | Silent (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- UBE2O | c.2661C>T p.R887= | Silent (SNP) | VAF 28/476 reads (6%) | catalogued as rs34371138; called by muse, mutect2
- AC244197.3 | c.*2327T>C | 3'UTR (SNP) | VAF 20/241 reads (8%) | called by muse, mutect2
- AJAP1 | c.*336G>T | 3'UTR (SNP) | VAF 32/421 reads (8%) | called by muse, mutect2
- DNAI4 | c.1581+55T>A | Intron (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- FRMD1 | chr6:168081458 C>A | 5'Flank (SNP) | VAF 19/510 reads (4%) | called by muse, mutect2
- PIKFYVE | c.322+314A>C | Intron (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- PNCK | c.539-44T>G | Intron (SNP) | VAF 27/660 reads (4%) | called by muse, mutect2
- TRIM9 | c.2070+85G>A | Intron (SNP) | VAF 32/378 reads (8%) | catalogued as rs771685381; called by muse, mutect2
